Somatic mutation profile of tumor specimen TCGA-ER-A198-06A (aliquot TCGA-ER-A198-06A-11D-A196-08) from TCGA case TCGA-ER-A198, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 46.3 years (16,916 days).
Specimen TCGA-ER-A198-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64e8517a-5e65-43ab-81ff-93dbfb0c59fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A198-10A (Blood Derived Normal), aliquot TCGA-ER-A198-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a18e653b-caed-4891-97b1-05c59d58f3a8

The open-access MAF lists 576 somatic variants for this specimen: 390 protein-altering or splice-affecting, 173 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 359, Silent 173, Nonsense Mutation 21, RNA 6, Splice Site 5, Intron 4, Splice Region 3, Translation Start Site 2, 3'Flank 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 12/34 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APC | c.3199C>T p.Q1067* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as rs137854571, CD941585, CM990158, COSV57329110; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASXL3 | c.2471C>T p.P824L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.025); catalogued as rs764053964, COSV52459496, COSV52465227; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- PRKCE | c.1795G>A p.E599K | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1553363925, COSV100077122, COSV60314142; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AASDHPPT | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.62); catalogued as rs1565409523, COSV53788448; called by muse, mutect2, varscan2
- ABCA1 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66057732; called by muse, mutect2, varscan2
- ABCA10 | c.4117G>A p.E1373K | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.036); catalogued as rs201375015, COSV52219205, COSV52227710; called by muse, mutect2, varscan2
- ABCA3 | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV57050414; called by muse, mutect2, varscan2
- ABCA8 | c.408T>A p.H136Q | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as COSV52195928; called by muse, mutect2, varscan2
- ABCC4 | c.1649A>G p.Y550C | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65310311; called by muse, mutect2, varscan2
- ABL1 | c.2126C>T p.S709F | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.309); catalogued as COSV59326286; called by muse, mutect2, varscan2
- ACKR3 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56020781; called by muse, mutect2, varscan2
- ACOT12 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.155); catalogued as COSV56893107; called by muse, mutect2, varscan2
- ACOX1 | c.1723C>T p.L575F | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV99503331; called by muse, mutect2, varscan2
- ACTG1 | c.502G>A p.G168S | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100111859; called by muse, mutect2, varscan2
- ADAMTS2 | c.2450C>T p.T817I | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as COSV52366740; called by muse, mutect2, varscan2
- ADGRB3 | c.2410G>A p.E804K | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as rs749382708, COSV100999996; called by muse, mutect2, varscan2
- ADGRF5 | c.1223G>A p.G408E | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51930699, COSV99345024; called by muse, mutect2, varscan2
- AGPAT4 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs755678797, COSV57242883; called by muse, mutect2, varscan2
- AIM2 | c.919G>A p.G307R | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV63698556; called by muse, mutect2, varscan2
- AKR1C2 | c.680G>A p.W227* | Nonsense Mutation (SNP) | VAF 17/40 reads (43%) | catalogued as COSV66332688; called by muse, mutect2, varscan2
- AL592490.1 | c.2135T>C p.V712A | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as COSV69424894; called by muse, mutect2, varscan2
- AL592490.1 | c.1036G>A p.D346N | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69424907; called by muse, mutect2, varscan2
- ALDH6A1 | c.1478G>A p.G493E | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63245853, COSV63245924; called by muse, mutect2, varscan2
- ALDH7A1 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68628724; called by muse, mutect2
- AMHR2 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV57685044; called by muse, mutect2, varscan2
- APCDD1 | c.268T>C p.F90L | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62372176; called by muse, mutect2, varscan2
- APOH | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs11551960, COSV52771692; called by muse, mutect2, varscan2
- ARHGEF11 | c.3761G>A p.G1254E | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.999); catalogued as COSV59352774, COSV59356032; called by muse, mutect2, varscan2
- ARHGEF5 | c.1440T>A p.D480E | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99282596; called by muse, mutect2, varscan2
- ARSF | c.963G>A p.M321I | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT tolerated (0.21); PolyPhen benign (0.199); catalogued as COSV63839085; called by muse, mutect2, varscan2
- ATP13A3 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as rs1044150573, COSV55462034; called by muse, mutect2, varscan2
- ATP2A2 | c.631G>A p.G211S | Missense Mutation (SNP) | VAF 71/229 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as COSV58042717; called by muse, mutect2, varscan2
- ATP8B4 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52710641; called by muse, mutect2, varscan2
- ATP9A | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs967937722, COSV58764076; called by muse, mutect2, varscan2
- ATXN3 | c.380G>A p.G127E | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV61493988; called by muse, mutect2, varscan2
- BACE2 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 66/164 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.358); catalogued as rs746160180, COSV57737930; called by muse, mutect2, varscan2
- BCLAF1 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.306); catalogued as COSV62140394; called by muse, mutect2, varscan2
- BMP6 | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs781421324, COSV51661574; called by muse, mutect2, varscan2
- BNC1 | c.2857C>T p.R953W | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs138921537; called by muse, mutect2, varscan2
- BRIP1 | c.911G>A p.G304E | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs1459305482, COSV51995351; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C10orf90 | c.2041C>T p.R681C | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1333506506, COSV52950556; called by muse, mutect2, varscan2
- C12orf50 | c.1124C>A p.P375Q | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.859); catalogued as COSV53893841; called by muse, mutect2, varscan2
- C22orf23 | c.525G>A p.M175I | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50777725; called by muse, mutect2, varscan2
- C4BPB | c.389C>A p.P130H | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.249); catalogued as COSV54690957, COSV54691654; called by muse, mutect2, varscan2
- C8G | c.340C>T p.L114F | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.4); catalogued as COSV56402444; called by muse, mutect2
- C9orf50 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs776911121, COSV65252214; called by muse, mutect2
- CALHM4 | c.797T>A p.I266N (on ENST00000368596 / NM_001366078.1; = p.I80N on NM_153036.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1437024602, COSV63985426; called by muse, mutect2, varscan2
- CCBE1 | c.757G>T p.G253W | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67949370; called by muse, mutect2, varscan2
- CCDC54 | c.376A>G p.I126V | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.124); catalogued as COSV53758157; called by muse, mutect2, varscan2
- CDC14A | c.1696C>T p.R566* | Nonsense Mutation (SNP) | VAF 27/92 reads (29%) | catalogued as rs376231837; called by muse, mutect2, varscan2
- CDH10 | c.1913G>A p.R638Q | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.532); catalogued as rs1402706331, COSV52570966, COSV52580434; called by muse, mutect2, varscan2
- CDH16 | c.2383G>A p.V795I | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV55335303; called by muse, mutect2, varscan2
- CENPE | c.4771G>A p.E1591K | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as COSV54377157; called by muse, mutect2, varscan2
- CFAP44 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV55609195; called by muse, mutect2, varscan2
- CFAP57 | c.1772C>T p.S591L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs756372048, COSV65263826; called by muse, mutect2, varscan2
- CFAP65 | c.3844C>T p.L1282= | Splice Region (SNP) | VAF 13/24 reads (54%) | catalogued as COSV58558735; called by muse, mutect2, varscan2
- CFAP97 | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.852); catalogued as COSV57109493; called by muse, mutect2, varscan2
- CHTF18 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.159); catalogued as rs780364796, COSV50099899, COSV50099916; called by muse, mutect2, varscan2
- CIT | c.3514C>T p.R1172C | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1455925579, COSV55862276; called by muse, mutect2, varscan2
- CMAS | c.1095G>A p.W365* | Nonsense Mutation (SNP) | VAF 11/34 reads (32%) | catalogued as COSV57556139; called by muse, mutect2, varscan2
- CMYA5 | c.1618C>T p.P540S | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.631); catalogued as COSV71404353; called by muse, mutect2, varscan2
- CNDP1 | c.841G>A p.G281S | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.49); PolyPhen probably damaging (1); catalogued as rs767889404, COSV100722202; called by muse, mutect2, varscan2
- CNTNAP2 | c.1094G>A p.S365N | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV62152363; called by muse, mutect2, varscan2
- COA7 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 31/74 reads (42%) | catalogued as rs149085843; called by muse, mutect2, varscan2
- COL14A1 | c.1165C>T p.P389S | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV52848687, COSV99919249; called by muse, mutect2, varscan2
- COL14A1 | c.5324A>T p.D1775V | Missense Mutation (SNP) | VAF 47/165 reads (28%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.454); catalogued as COSV52848702; called by muse, mutect2, varscan2
- COL4A4 | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.168); catalogued as COSV61630157; called by muse, mutect2, varscan2
- CPED1 | c.3028G>A p.V1010I | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV59998361; called by muse, mutect2, varscan2
- CPT1B | c.1703C>T p.A568V | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56415395; called by muse, mutect2, varscan2
- CRKL | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62882811, COSV62883784; called by muse, mutect2, varscan2
- CRTAC1 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.962); catalogued as rs775042630, COSV54005438; called by muse, varscan2
- CRYBA4 | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.709); catalogued as rs776063006, COSV61321391; called by muse, mutect2, varscan2
- CSF2RA | c.569A>G p.N190S | Missense Mutation (SNP) | VAF 139/361 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0.1); catalogued as rs1286771141, COSV62623759; called by muse, mutect2, varscan2
- CSMD3 | c.5734G>A p.G1912R (on ENST00000297405 / NM_001363185.1; = p.G1808R on NM_052900.3) | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52119825, COSV52211131; called by muse, mutect2, varscan2
- CWH43 | c.1108A>C p.K370Q | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.796); catalogued as COSV56936707; called by muse, mutect2, varscan2
- CX3CR1 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as COSV64193276; called by muse, mutect2, varscan2
- CYP2C19 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as COSV64907039; called by muse, varscan2
- DAB2IP | c.739G>A p.G247S (on ENST00000408936; = p.G219S on NM_032552.3) | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV52255470; called by muse, mutect2, varscan2
- DDIT3 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV56252929; called by muse, mutect2, varscan2
- DDO | c.752G>A p.S251N (on ENST00000368924 / NM_001368172.1; = p.S192N on NM_004032.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/255 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.759); catalogued as COSV64469780; called by muse, mutect2, varscan2
- DGAT2L6 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs369585641, COSV60717250; called by muse, mutect2, varscan2
- DHX37 | c.1291A>T p.K431* | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as COSV58132635; called by muse, mutect2, varscan2
- DNAH5 | c.11947C>T p.L3983F | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV54208857; called by muse, mutect2, varscan2
- DNAH5 | c.10138G>A p.E3380K | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54208869, COSV54212682; called by muse, mutect2, varscan2
- DNAH7 | c.9632C>T p.S3211F | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV56750900; called by muse, mutect2, varscan2
- DNAH7 | c.2576C>T p.A859V | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as COSV56754832; called by muse, mutect2, varscan2
- DNAH8 | c.8233C>T p.P2745S | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as rs762468209, COSV59430323; called by muse, mutect2, varscan2
- DNM3 | c.697G>A p.G233R | Missense Mutation (SNP) | VAF 2/14 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62471092; called by muse, mutect2
- DRD2 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0.309); catalogued as COSV60755053; called by muse, mutect2, varscan2
- EBNA1BP2 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52539472; called by muse, mutect2, varscan2
- EDC4 | c.2666C>T p.A889V | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.219); catalogued as rs778986211, COSV59302089; called by muse, mutect2, varscan2
- EML4 | c.1994G>A p.R665K | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.2); catalogued as COSV100581193, COSV59294613; called by muse, mutect2, varscan2
- EML5 | c.4864A>T p.K1622* (on ENST00000380664; = p.K1630* on NM_183387.3) | Nonsense Mutation (SNP) | VAF 22/50 reads (44%) | catalogued as COSV61342702; called by muse, mutect2, varscan2
- EPN2 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV59060167; called by muse, mutect2, varscan2
- EPS15L1 | c.2447C>T p.P816L | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV50167511; called by muse, mutect2, varscan2
- ERICH3 | c.1569G>A p.M523I | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.155); catalogued as COSV58601188; called by muse, mutect2, varscan2
- ETFBKMT | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 55/188 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); catalogued as COSV63189019; called by muse, mutect2, varscan2
- EZHIP | c.265A>T p.I89L | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV100539507; called by muse, mutect2, varscan2
- F10 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1217477767, CM980646, COSV65020933; called by muse, mutect2, varscan2
- F13A1 | c.1985G>A p.R662Q | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs781240042, COSV53552778; called by muse, mutect2, varscan2
- F13A1 | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM103179, COSV53554649; called by muse, mutect2, varscan2
- F5 | c.2779C>T p.P927S | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV63121469; called by muse, mutect2, varscan2
- FAM135B | c.1074A>C p.K358N | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52709988; called by muse, mutect2, varscan2
- FAM149A | c.1927G>A p.V643M (on ENST00000356371 / NM_001367768.2; = p.V352M on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs149087810; called by muse, mutect2, varscan2
- FAM149A | c.1928T>A p.V643E (on ENST00000356371 / NM_001367768.2; = p.V352E on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.058); catalogued as COSV99906355; called by muse, mutect2, varscan2
- FAM170A | c.984G>A p.R328= | Splice Region (SNP) | VAF 27/68 reads (40%) | catalogued as COSV100088633, COSV58924153; called by muse, mutect2, varscan2
- FAM171A1 | c.1237C>T p.P413S | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100968087; called by muse, mutect2, varscan2
- FAM221B | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV65073698; called by muse, mutect2, varscan2
- FAM24B | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0.079); catalogued as COSV59025853; called by muse, mutect2, varscan2
- FAM47A | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 44/61 reads (72%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.958); catalogued as COSV60494538; called by muse, mutect2, varscan2
- FANCA | c.1490C>T p.P497L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769716206, COSV66880759; called by muse, mutect2
- FASN | c.4094C>T p.P1365L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs902738984, COSV100147424; called by muse, mutect2, varscan2
- FAT4 | c.7949C>T p.P2650L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58674446; called by muse, mutect2, varscan2
- FAT4 | c.9892C>T p.P3298S | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1054386288, COSV58674458; called by muse, mutect2, varscan2
- FCGR2B | c.433G>A p.G145R | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52682563; called by muse, mutect2, varscan2
- FER1L6 | c.3397G>C p.D1133H | Missense Mutation (SNP) | VAF 49/214 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV67548487, COSV67550767; called by muse, mutect2, varscan2
- FERMT1 | c.1344G>A p.M448I | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as COSV54091455; called by muse, mutect2, varscan2
- FGD3 | c.708C>G p.I236M | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61595913; called by muse, mutect2, varscan2
- FLAD1 | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 70/207 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.114); catalogued as COSV99422137; called by muse, mutect2, varscan2
- FLAD1 | c.1322C>T p.P441L | Missense Mutation (SNP) | VAF 67/206 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as COSV99422144; called by muse, mutect2, varscan2
- FLNC | c.4237A>C p.T1413P | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.278); catalogued as COSV57951830; called by muse, mutect2, varscan2
- FLT3 | c.166G>A p.V56I | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.001); catalogued as COSV54046497; called by muse, mutect2, varscan2
- FMN2 | c.2119G>A p.G707S | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.003); catalogued as COSV60415502, COSV60420397; called by muse, mutect2, varscan2
- FREM2 | c.5137G>A p.D1713N | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV54830729; called by muse, mutect2, varscan2
- FSIP2 | c.17989G>A p.E5997K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs773605266, COSV58080005; called by muse, mutect2, varscan2
- GALNT17 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.709); catalogued as rs866308070, COSV100355048, COSV61148982; called by muse, mutect2, varscan2
- GCC2 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV100565275; called by muse, mutect2, varscan2
- GCNT1 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.921); catalogued as COSV65057009; called by muse, mutect2, varscan2
- GDF5 | c.1096G>A p.D366N | Missense Mutation (SNP) | VAF 76/183 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.034); catalogued as rs766838573, COSV65499834, COSV65503910; called by muse, mutect2, varscan2
- GLRA1 | c.1309A>G p.I437V (on ENST00000455880 / NM_001146040.2; = p.I429V on NM_000171.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.491); catalogued as COSV51008229; called by muse, mutect2, varscan2
- GNA15 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53585355; called by muse, mutect2, varscan2
- GPATCH8 | c.1144C>T p.R382* | Nonsense Mutation (SNP) | VAF 30/110 reads (27%) | catalogued as COSV59193546; called by muse, mutect2, varscan2
- GPBP1 | c.1217C>T p.P406L | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99302488; called by muse, mutect2, varscan2
- GPR101 | c.1129C>T p.P377S | Missense Mutation (SNP) | VAF 47/67 reads (70%) | SIFT tolerated (0.1); PolyPhen benign (0.212); catalogued as rs1354242756, COSV53237717; called by muse, mutect2, varscan2
- GPR83 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.421); catalogued as COSV54717775; called by muse, mutect2, varscan2
- GRAMD1B | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.549); catalogued as COSV59201283; called by muse, mutect2, varscan2
- GRAMD2B | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.422); catalogued as rs755232494, COSV53510569; called by muse, mutect2, varscan2
- GRID1 | c.1983G>A p.M661I | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.968); catalogued as COSV60017086, COSV60034166; called by muse, mutect2, varscan2
- GTF2F1 | c.802G>A p.G268S | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1295165131, COSV66725082; called by muse, mutect2, varscan2
- GTF2IRD1 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs1480640371, COSV56084939; called by muse, mutect2, varscan2
- HAP1 | c.1837G>A p.E613K (on ENST00000310778 / NM_001367460.1; = p.E561K on NM_177977.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/208 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV57877576; called by muse, mutect2, varscan2
- HECW1 | c.2728C>T p.P910S | Missense Mutation (SNP) | VAF 58/97 reads (60%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs762517053, COSV101222903; called by muse, mutect2, varscan2
- HERC2 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.025); catalogued as COSV55311508; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.574G>A p.E192K (on ENST00000354667 / NM_031243.3; = p.E180K on NM_002137.4) | Missense Mutation (SNP) | VAF 55/89 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV61158312; called by muse, mutect2, varscan2
- HPD | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.106); catalogued as COSV100000237, COSV56641249; called by muse, mutect2, varscan2
- HRNR | c.3094G>A p.G1032R | Missense Mutation (SNP) | VAF 72/213 reads (34%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.781); catalogued as COSV64255189; called by muse, mutect2, varscan2
- HSD17B12 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0.022); catalogued as rs771094734, COSV53497468; called by muse, mutect2, varscan2
- HYDIN | c.9316A>C p.K3106Q | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV59251099; called by muse, mutect2, varscan2
- IKBKE | c.1367G>A p.R456Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs782313349, COSV65624377; called by muse, mutect2, varscan2
- IL17B | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.3); catalogued as rs754779395, COSV51002150; called by muse, mutect2, varscan2
- IL1B | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs775562734, COSV54521186; called by muse, mutect2, varscan2
- IL27 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); catalogued as COSV60489212; called by muse, mutect2, varscan2
- IL27 | c.643T>A p.S215T | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.345); catalogued as COSV100112286; called by muse, mutect2, varscan2
- ING1 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.005); catalogued as rs1232581439, COSV58167138; called by muse, mutect2, varscan2
- IP6K3 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53389326; called by muse, mutect2, varscan2
- ITGA7 | c.634C>G p.L212V | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.083); catalogued as COSV57692681; called by muse, mutect2, varscan2
- ITGB8 | c.44G>A p.C15Y | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.123); catalogued as rs1330014152, COSV56005569; called by muse, mutect2
- JAKMIP1 | c.1846G>A p.D616N | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV99288785; called by muse, mutect2, varscan2
- KAT7 | c.1709G>A p.G570E | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52013380; called by muse, mutect2, varscan2
- KATNAL2 | c.866G>A p.G289E (on ENST00000356157 / NM_001353899.1; = p.G217E on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55294710; called by muse, mutect2, varscan2
- KCNB2 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101578989, COSV73049233; called by muse, mutect2, varscan2
- KCNK1 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1393902253, COSV64034525; called by muse, mutect2, varscan2
- KCNQ2 | c.2588G>A p.G863D (on ENST00000359125 / NM_172107.4; = p.G835D on NM_004518.6) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.745); catalogued as COSV100609846; called by muse, mutect2
- KEL | c.1144C>T p.Q382* | Nonsense Mutation (SNP) | VAF 13/72 reads (18%) | catalogued as COSV62333730; called by muse, mutect2, varscan2
- KIAA0319 | c.2445T>G p.S815R | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.522); catalogued as COSV65496846; called by muse, mutect2, varscan2
- KIF21A | c.2702G>A p.R901K (on ENST00000361418 / NM_001378440.1; = p.R888K on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as COSV100735529, COSV62768248; called by muse, mutect2, varscan2
- KLF14 | c.496T>C p.F166L | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV60588452; called by muse, mutect2, varscan2
- KLHL4 | c.1739G>A p.G580E | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV64139738; called by muse, mutect2, varscan2
- KLK14 | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.022); catalogued as rs372308187; called by muse, mutect2, varscan2
- KMT2E | c.794C>T p.S265L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.164); catalogued as COSV57570453, COSV57580643; called by muse, mutect2, varscan2
- KRT2 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs532824132, COSV59009066; called by muse, mutect2, varscan2
- LAMA4 | c.1960-1G>A p.X654_splice (on ENST00000230538 / NM_001105206.3; = p.X647_splice on NM_002290.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 21/71 reads (30%) | catalogued as rs781854923, COSV57892809; called by muse, mutect2, varscan2
- LARP1 | c.2000C>T p.S667L (on ENST00000518297 / NM_033551.3; = p.S590L on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV60425259; called by muse, mutect2, varscan2
- LHFPL4 | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 60/131 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754454753, COSV55000962; called by muse, mutect2, varscan2
- LRP1B | c.2845G>A p.E949K | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as rs559134345, COSV67194336; called by muse, mutect2, varscan2
- LRRK2 | c.543C>G p.C181W | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54146401; called by muse, mutect2, varscan2
- LSAMP | c.428T>G p.V143G | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV61279066; called by muse, mutect2, varscan2
- MACF1 | c.4019C>T p.S1340F | Missense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as COSV58362776; called by muse, mutect2, varscan2
- MACROH2A1 | c.290G>A p.G97E | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.268); catalogued as rs1415059338, COSV100427545; called by muse, mutect2, varscan2
- MACROH2A1 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.802); catalogued as COSV100427546; called by muse, mutect2, varscan2
- MAGEA6 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 80/111 reads (72%) | SIFT tolerated (0.79); PolyPhen benign (0.183); catalogued as COSV61449432; called by muse, mutect2, varscan2
- MAGEE1 | c.1352A>C p.K451T | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV63909092; called by muse, mutect2, varscan2
- MAGI1 | c.1928C>T p.T643I | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58317295, COSV58347489; called by muse, mutect2, varscan2
- MAJIN | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs750259177, COSV57262444; called by muse, mutect2, varscan2
- MAN2C1 | c.2452C>T p.R818C | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.862); catalogued as rs780059888, COSV51226791; called by muse, mutect2, varscan2
- MAP2 | c.2738C>T p.S913L | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1424119999, COSV52283659; called by muse, mutect2, varscan2
- MAP2K7 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.056); catalogued as rs1238524673, COSV67607728; called by muse, mutect2, varscan2
- MAP3K1 | c.633G>A p.V211= | Splice Region (SNP) | VAF 12/40 reads (30%) | catalogued as COSV68122243; called by muse, mutect2, varscan2
- MAP3K21 | c.1064G>A p.G355E | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1558456152, COSV64043620; called by muse, varscan2
- MARCO | c.988C>T p.P330S | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV59052467; called by muse, mutect2, varscan2
- MAST4 | c.7163A>C p.E2388A (on ENST00000403625 / NM_001164664.2; = p.E2199A on NM_015183.3) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.46); catalogued as COSV55118034; called by muse, mutect2, varscan2
- MAT2A | c.1086-1G>A p.X362_splice | Splice Site (SNP) | VAF 14/42 reads (33%) | catalogued as COSV52087229; called by muse, mutect2, varscan2
- MDN1 | c.9397C>T p.Q3133* | Nonsense Mutation (SNP) | VAF 43/144 reads (30%) | catalogued as COSV101020833; called by muse, mutect2, varscan2
- MIA3 | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 46/83 reads (55%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as COSV60510539, COSV99049272; called by muse, mutect2, varscan2
- MLH3 | c.2917C>T p.P973S | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV53152736; called by muse, mutect2, varscan2
- MLPH | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as COSV52818590; called by muse, mutect2, varscan2
- MMP10 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54245625; called by muse, mutect2, varscan2
- MORC2 | c.296A>T p.Q99L (on ENST00000397641 / NM_001303256.3; = p.Q37L on NM_014941.3) | Missense Mutation (SNP) | VAF 61/147 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53196184; called by muse, mutect2, varscan2
- MORC3 | c.1726G>A p.D576N | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV68687879; called by muse, mutect2, varscan2
- MRAP2 | c.567T>G p.I189M | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV57631698; called by muse, mutect2, varscan2
- MRPS25 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV53741069; called by muse, mutect2, varscan2
- MSH5 | c.1778C>T p.P593L | Missense Mutation (SNP) | VAF 160/408 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65208895; called by muse, mutect2, varscan2
- MTA2 | c.133C>T p.L45F | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); catalogued as rs762827302, COSV53870824; called by muse, mutect2, varscan2
- MUC16 | c.28891C>T p.P9631S | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.115); catalogued as rs961853218, COSV67450604, COSV67500376; called by muse, mutect2, varscan2
- MUC16 | c.23060C>T p.P7687L | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV67450618; called by muse, mutect2, varscan2
- MUC5B | c.10708G>A p.G3570S | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV71590432; called by muse, varscan2
- MYBL2 | c.1213A>G p.T405A | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53828016; called by muse, varscan2
- MYBL2 | c.1220C>T p.P407L | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53828029; called by muse, varscan2
- MYCT1 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs748344102, COSV100924088, COSV65890890; called by muse, mutect2, varscan2
- MYH2 | c.2554G>A p.E852K | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV55433028; called by muse, mutect2, varscan2
- MYH6 | c.1744C>T p.H582Y | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62448420; called by muse, mutect2, varscan2
- MYLK3 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.78); catalogued as COSV67362876; called by muse, mutect2, varscan2
- MYO9A | c.5726C>T p.S1909L | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61848308; called by muse, mutect2, varscan2
- MYOCD | c.1507G>A p.G503R | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV58498663; called by muse, varscan2
- NCAPG2 | c.2996C>T p.T999I | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV99316570; called by muse, mutect2, varscan2
- NCAPG2 | c.2995A>T p.T999S | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV99316573; called by muse, mutect2, varscan2
- NCAPH2 | c.421-1G>A p.X141_splice | Splice Site (SNP) | VAF 27/76 reads (36%) | catalogued as rs1305356395, COSV55366891; called by muse, mutect2, varscan2
- NEU4 | c.44G>A p.R15Q (on ENST00000391969 / NM_001167602.3; = p.R27Q on NM_080741.4) | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs752929700, COSV100372162, COSV57989726; called by muse, mutect2, varscan2
- NEXN | c.338G>A p.R113K | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV53942038; called by muse, mutect2, varscan2
- NIBAN1 | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs770671120, COSV62283402; called by muse, mutect2, varscan2
- NKAIN3 | c.169T>G p.Y57D | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV60652146; called by muse, mutect2, varscan2
- NLRP12 | c.1153G>A p.G385S | Missense Mutation (SNP) | VAF 86/236 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs1259787589, COSV60744323, COSV60745923; called by muse, mutect2, varscan2
- NME3 | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99167714; called by muse, mutect2, varscan2
- NPAS1 | c.469G>A p.G157R | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71383882; called by muse, mutect2, varscan2
- NPHP4 | c.2260G>A p.G754R | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs373962831, CM022973; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPHS1 | c.2336G>A p.G779E | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.381); catalogued as COSV62286709; called by muse, mutect2, varscan2
- NPSR1 | c.593G>T p.W198L | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62197315; called by muse, mutect2, varscan2
- NPTXR | c.1196G>A p.G399E | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267606249, COSV60727837, COSV60729766; called by muse, mutect2, varscan2
- NR1D2 | c.1217C>T p.S406L | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as rs1384626966, COSV56990936; called by muse, mutect2, varscan2
- NRXN2 | c.3893G>A p.G1298E | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55448840, COSV99636439; called by muse, mutect2, varscan2
- NUP98 | c.3430C>T p.R1144C (on ENST00000359171 / NM_001365126.1; = p.R1127C on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867822493, COSV61429434; called by muse, mutect2, varscan2
- NXPE1 | c.1264G>A p.E422K (on ENST00000424269; = p.E280K on NM_152315.5) | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.378); catalogued as rs1367514781, COSV52627475; called by muse, mutect2, varscan2
- NXPE4 | c.412C>A p.L138M | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.841); catalogued as COSV64943502; called by muse, mutect2, varscan2
- OLFM3 | c.1256C>T p.S419F (on ENST00000338858 / NM_001288821.1; = p.S399F on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV58796376; called by muse, mutect2, varscan2
- OR13C3 | c.774G>A p.M258I | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV66165629; called by muse, mutect2, varscan2
- OR2M5 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 49/161 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63545620; called by muse, mutect2, varscan2
- OR2T27 | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.972); catalogued as COSV100788083; called by mutect2, varscan2
- OR2T27 | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); catalogued as rs772619678; called by mutect2, varscan2
- OR51F2 | c.172C>T p.H58Y | Missense Mutation (SNP) | VAF 52/129 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs113742153; called by muse, mutect2, varscan2
- OR51L1 | c.111T>A p.Y37* | Nonsense Mutation (SNP) | VAF 38/109 reads (35%) | catalogued as COSV58624096; called by muse, mutect2, varscan2
- OR51L1 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.417); catalogued as rs1239718091, COSV58624107; called by muse, mutect2, varscan2
- OR6T1 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as rs375228674; called by muse, mutect2, varscan2
- OR8B8 | c.804G>A p.M268I | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.024); catalogued as COSV60144015; called by muse, mutect2, varscan2
- OR8D1 | c.383G>A p.S128N | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100766674, COSV63441784; called by muse, mutect2, varscan2
- OSGIN2 | c.884G>A p.G295E | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.635); catalogued as COSV52407375; called by muse, mutect2, varscan2
- PALB2 | c.2750T>A p.V917D | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs763645981, COSV55162954; called by muse, mutect2, varscan2
- PAN2 | c.2445G>A p.M815I (on ENST00000425394 / NM_001127460.3; = p.M811I on NM_014871.5) | Missense Mutation (SNP) | VAF 66/161 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.137); catalogued as COSV57752978; called by muse, mutect2, varscan2
- PBK | c.635G>A p.W212* | Nonsense Mutation (SNP) | VAF 13/43 reads (30%) | catalogued as COSV100107390, COSV57272991; called by muse, mutect2, varscan2
- PC | c.1867C>T p.P623S | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774882026, COSV67369447; called by muse, mutect2, varscan2
- PCDHA1 | c.1549G>A p.V517M | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs373804553; called by muse, mutect2, varscan2
- PCDHB2 | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV50564968; called by muse, mutect2, varscan2
- PCLO | c.10304G>A p.R3435Q | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.387); catalogued as rs775369053, COSV61620385; called by muse, mutect2, varscan2
- PCLO | c.7007C>T p.S2336F | Missense Mutation (SNP) | VAF 97/175 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.082); catalogued as rs1323595066, COSV61620399; called by muse, mutect2, varscan2
- PDE7B | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.159); catalogued as rs752633814, COSV57493770; called by muse, mutect2, varscan2
- PDGFRL | c.730G>A p.V244I | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV52410965; called by muse, mutect2, varscan2
- PDHA2 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.345); catalogued as COSV54777671, COSV54777930; called by muse, varscan2
- PDZD3 | c.1552G>A p.G518R (on ENST00000531114; = p.G438R on NM_024791.4) | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100501208; called by muse, mutect2, varscan2
- PEG3 | c.2608G>A p.D870N | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV55627384; called by muse, mutect2, varscan2
- PHRF1 | c.3430G>A p.E1144K (on ENST00000264555 / NM_001286581.2; = p.E1143K on NM_020901.4) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs764885272, COSV52752230; called by muse, mutect2, varscan2
- PIH1D1 | c.562C>T p.Q188* | Nonsense Mutation (SNP) | VAF 27/77 reads (35%) | catalogued as COSV51806499; called by muse, mutect2, varscan2
- PIK3R6 | c.392G>A p.G131E | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61001901; called by muse, mutect2, varscan2
- PKD1 | c.5558C>T p.T1853I | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as rs375128600; called by muse, mutect2
- PLAG1 | c.836C>T p.S279L | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as COSV57609686, COSV57614858; called by muse, mutect2, varscan2
- PLCE1 | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 29/63 reads (46%) | catalogued as COSV53340283; called by muse, mutect2, varscan2
- PLK3 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.029); catalogued as COSV59499239; called by muse, mutect2, varscan2
- POLD1 | c.2731G>A p.D911N | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs878854541, COSV54529777, COSV54533183; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPFIA2 | c.639T>G p.N213K | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.979); catalogued as COSV61023078; called by muse, mutect2, varscan2
- PPP3CB | c.1309C>T p.P437S | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV61151169; called by muse, mutect2, varscan2
- PRAMEF19 | c.1237C>T p.P413S | Missense Mutation (SNP) | VAF 116/313 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV101069347; called by muse, mutect2, varscan2
- PRB1 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 110/295 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.104); catalogued as COSV53702699; called by muse, mutect2, varscan2
- PRH1 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 46/230 reads (20%) | SIFT tolerated, low confidence (0.53); PolyPhen probably damaging (0.932); catalogued as COSV101457481; called by muse, varscan2
- PROM2 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.197); catalogued as rs1186255611, COSV58297012; called by muse, mutect2, varscan2
- PRSS1 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.061); catalogued as COSV61191072; called by muse, varscan2
- PSG11 | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 58/162 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0.045); catalogued as COSV60453936; called by muse, mutect2, varscan2
- PTCHD3 | c.2188C>T p.P730S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.684); catalogued as COSV71256353; called by muse, mutect2, varscan2
- PTGFRN | c.1795C>T p.P599S | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.403); catalogued as COSV67797966; called by muse, mutect2, varscan2
- RANBP17 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs765562410, COSV66645615; called by muse, mutect2, varscan2
- RARA | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.968); catalogued as COSV54190312, COSV54191073; called by muse, mutect2, varscan2
- RAVER1 | c.1798G>A p.A600T (on ENST00000615032; = p.G726D on NM_133452.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.816); catalogued as rs1480751072, COSV53344181; called by muse, mutect2, varscan2
- RGS9 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.437); catalogued as COSV52225688; called by muse, mutect2, varscan2
- RILPL2 | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 112/284 reads (39%) | catalogued as rs1555259046, COSV54912047; called by muse, mutect2, varscan2
- RIMKLA | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 106/293 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.044); catalogued as COSV68909685, COSV68909795; called by muse, mutect2, varscan2
- RING1 | c.193C>T p.L65F | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1562450864, COSV63002327; called by muse, mutect2, varscan2
- RIOK1 | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV53571484; called by muse, mutect2, varscan2
- RNF103 | c.1972T>G p.C658G | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV52893949; called by muse, mutect2, varscan2
- RP1 | c.4564G>A p.G1522S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as rs762338185, COSV99606428, COSV99607179; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RP1L1 | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 62/154 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV66751992; called by muse, mutect2, varscan2
- RPUSD1 | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV50099896; called by muse, mutect2, varscan2
- RRP8 | c.275G>A p.G92E | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as COSV54449034; called by muse, mutect2, varscan2
- RSPH9 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV64664274; called by muse, mutect2, varscan2
- RTN3 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.42); catalogued as COSV58027296; called by muse, mutect2, varscan2
- RXFP2 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV53633198, COSV53633693, COSV53639770; called by muse, mutect2, varscan2
- SBNO1 | c.659C>T p.P220L (on ENST00000420886; = p.P219L on NM_018183.5) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.186); catalogued as COSV99928810; called by muse, mutect2
- SBNO1 | c.658C>T p.P220S (on ENST00000420886; = p.P219S on NM_018183.5) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.382); catalogued as COSV57341862; called by muse, mutect2
- SCARF2 | c.2524C>T p.P842S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.625); catalogued as rs1012115551, COSV56731251; called by muse, mutect2, varscan2
- SCG3 | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 40/60 reads (67%) | catalogued as COSV55020272; called by muse, mutect2, varscan2
- SCN10A | c.4504G>A p.E1502K | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs868500654, COSV71860539; called by muse, mutect2, varscan2
- SCN3A | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs759649419, COSV51803430; called by muse, mutect2, varscan2
- SCN7A | c.2189C>T p.S730L | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV69269517; called by muse, mutect2
- SCN9A | c.3889C>T p.P1297S (on ENST00000303354; = p.P1286S on NM_002977.3) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57602572; called by muse, mutect2, varscan2
- SDK2 | c.1805C>T p.T602I | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV66182407; called by muse, mutect2, varscan2
- SEL1L3 | c.1889C>T p.S630L | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs780416105, COSV53537387; called by muse, mutect2, varscan2
- SEPTIN12 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 49/165 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as rs375316506; called by muse, mutect2, varscan2
- SIGLEC11 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.026); catalogued as COSV101389105, COSV70222203; called by muse, mutect2, varscan2
- SIGLEC11 | c.238C>A p.P80T | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101389108; called by muse, mutect2, varscan2
- SIM1 | c.976G>A p.V326I | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs41285857, COSV53489607; called by muse, mutect2, varscan2
- SLAIN2 | c.1109G>A p.G370E | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.656); catalogued as COSV51904633; called by muse, mutect2, varscan2
- SLC2A14 | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs755077699, COSV61585727; called by muse, mutect2, varscan2
- SLC36A1 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 96/291 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54652429; called by muse, mutect2, varscan2
- SLC39A2 | c.755G>A p.G252E | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV53869061; called by muse, mutect2, varscan2
- SLC45A4 | c.1546C>T p.L516F (on ENST00000517878 / NM_001286646.2; = p.L465F on NM_001080431.2) | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV50133892; called by muse, mutect2, varscan2
- SLCO4C1 | c.1288C>T p.P430S | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1404019563, COSV60513385; called by muse, mutect2, varscan2
- SLIT2 | c.4282C>T p.L1428F | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV56563344; called by muse, mutect2, varscan2
- SLIT3 | c.4472G>A p.R1491H | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs140403495; called by muse, mutect2, varscan2
- SLK | c.1934C>T p.S645L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs757446564, COSV59824226; called by muse, mutect2
- SLMAP | c.1622G>A p.R541Q (on ENST00000428312 / NM_001377924.1; = p.R603Q on NM_007159.5) | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as rs1359077850, COSV55845069; called by muse, mutect2, varscan2
- SMO | c.2312C>T p.S771F | Missense Mutation (SNP) | VAF 61/116 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.598); catalogued as rs1471453753, COSV50824720; called by muse, mutect2, varscan2
- SNRNP200 | c.1291C>T p.P431S | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV60487831; called by muse, mutect2, varscan2
- SORL1 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.112); catalogued as rs548615007, COSV52750567, COSV52753560; called by muse, mutect2, varscan2
- SOS2 | c.3451C>T p.P1151S | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV53564508; called by muse, mutect2, varscan2
- SPACA7 | c.373C>T p.H125Y | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.198); catalogued as rs1244291109, COSV52098307; called by muse, mutect2, varscan2
- SRRM2 | c.6589C>T p.P2197S | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs748391558, COSV51940037; called by muse, mutect2, varscan2
- ST6GAL2 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 16/46 reads (35%) | PolyPhen probably damaging (0.999); catalogued as COSV62416038; called by muse, mutect2
- STRC | c.4648G>A p.D1550N | Missense Mutation (SNP) | VAF 40/64 reads (63%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.464); catalogued as COSV100294452; called by muse, mutect2, varscan2
- SUGP2 | c.2686G>A p.D896N | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs932735663, COSV58256018; called by muse, mutect2, varscan2
- SUPV3L1 | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.284); catalogued as COSV62844772; called by muse, mutect2, varscan2
- TAGAP | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.02); catalogued as COSV57850750, COSV57853202; called by muse, mutect2, varscan2
- TCF4 | c.1025C>T p.S342L | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV61891908, COSV61893497; called by muse, mutect2, varscan2
- TELO2 | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV51976350; called by muse, mutect2, varscan2
- TENM3 | c.6397G>A p.D2133N | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.977); catalogued as COSV69300996; called by muse, mutect2, varscan2
- TFAP4 | c.352C>T p.Q118* | Nonsense Mutation (SNP) | VAF 42/133 reads (32%) | catalogued as COSV52596970; called by muse, mutect2, varscan2
- THSD7B | c.2023G>A p.E675K | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV55661864, COSV55675955; called by muse, mutect2, varscan2
- THSD7B | c.3067C>T p.R1023* | Nonsense Mutation (SNP) | VAF 13/32 reads (41%) | catalogued as rs750153977, COSV55661886; called by muse, mutect2, varscan2
- TM7SF2 | c.943C>T p.R315* | Nonsense Mutation (SNP) | VAF 40/134 reads (30%) | catalogued as rs769493365, COSV54206318; called by muse, mutect2, varscan2
- TMC5 | c.2091-1G>A p.X697_splice (on ENST00000396229 / NM_001105248.1; = p.X451_splice on NM_024780.5) | Splice Site (SNP) | VAF 25/69 reads (36%) | catalogued as COSV54901553; called by muse, mutect2, varscan2
- TMEM119 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.107); catalogued as rs1444662748, COSV67188495; called by muse, mutect2, varscan2
- TMEM209 | c.776G>A p.G259E | Missense Mutation (SNP) | VAF 56/175 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.885); catalogued as COSV61021737; called by muse, mutect2
- TMPRSS15 | c.2165G>A p.G722E | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as COSV53035862; called by muse, mutect2, varscan2
- TNKS | c.712A>T p.M238L | Missense Mutation (SNP) | VAF 74/167 reads (44%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1311558062, COSV60052995; called by muse, mutect2, varscan2
- TNN | c.1238T>G p.L413R | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53422669; called by muse, mutect2, varscan2
- TNRC6B | c.4271C>T p.A1424V (on ENST00000454349 / NM_001162501.2; = p.A1314V on NM_015088.3) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV57290422; called by muse, mutect2, varscan2
- TPD52L3 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.097); catalogued as COSV58828016; called by muse, mutect2, varscan2
- TRAK1 | c.1435G>A p.E479K (on ENST00000327628 / NM_001349247.2; = p.E421K on NM_014965.5) | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.049); catalogued as COSV58256445; called by muse, mutect2, varscan2
- TRHDE | c.1460G>A p.R487K | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); catalogued as COSV53836837; called by muse, mutect2, varscan2
- TRPM5 | c.1631G>A p.G544D | Missense Mutation (SNP) | VAF 59/106 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV99329621; called by muse, mutect2, varscan2
- TRPM5 | c.1630G>A p.G544S | Missense Mutation (SNP) | VAF 58/105 reads (55%) | SIFT tolerated (0.75); PolyPhen benign (0.09); catalogued as rs1181419945, COSV99329625; called by muse, mutect2, varscan2
- TRRAP | c.5003G>T p.R1668L (on ENST00000359863 / NM_001244580.1; = p.R1650L on NM_003496.3) | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.416); catalogued as COSV62840509; called by muse, mutect2, varscan2
- TTC37 | c.757C>T p.L253F | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV62453795; called by muse, mutect2, varscan2
- TTN | c.63937G>A p.D21313N (on ENST00000591111; = p.D13889N on NM_003319.4) | Missense Mutation (SNP) | VAF 15/39 reads (38%) | PolyPhen possibly damaging (0.647); catalogued as COSV59919843; called by muse, mutect2, varscan2
- TTN | c.19406G>A p.G6469E (on ENST00000591111; = p.G5542E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | PolyPhen probably damaging (1); catalogued as COSV100597120, COSV59919874; called by muse, mutect2, varscan2
- TUBGCP3 | c.2419G>A p.E807K | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as rs1481901685, COSV56184747; called by muse, mutect2, varscan2
- TXNDC5 | c.1004C>T p.T335I | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.353); catalogued as rs969762443, COSV51661588; called by muse, mutect2, varscan2
- TYR | c.1522C>T p.P508S | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV54471376; called by muse, mutect2, varscan2
- UGT1A8 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs373133620; called by muse, mutect2, varscan2
- UNC13B | c.3040G>A p.D1014N | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65931820; called by muse, mutect2, varscan2
- UNC13C | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV52849155, COSV52868879; called by muse, mutect2, varscan2
- UNC5CL | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV55109208; called by muse, mutect2, varscan2
- USH2A | c.13951C>T p.P4651S | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.067); catalogued as COSV56336443, COSV56360452; called by muse, mutect2, varscan2
- USP32 | c.1709T>C p.L570P | Missense Mutation (SNP) | VAF 134/340 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56265122; called by muse, mutect2, varscan2
- USP9X | c.88C>T p.Q30* | Nonsense Mutation (SNP) | VAF 8/11 reads (73%) | catalogued as COSV61066820; called by muse, mutect2, varscan2
- VAT1 | c.958A>G p.N320D | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV55895977; called by muse, mutect2, varscan2
- VCAN | c.2764G>A p.G922R | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.484); catalogued as rs749584783, COSV54098915; called by muse, mutect2, varscan2
- VNN1 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as COSV63389447; called by muse, mutect2, varscan2
- VPS13B | c.6466C>G p.L2156V | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV62135339; called by muse, mutect2, varscan2
- VPS39 | c.2012C>T p.S671F (on ENST00000348544 / NM_001301138.2; = p.S660F on NM_015289.5) | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100529531, COSV58788192; called by muse, mutect2, varscan2
- VSX2 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as rs1273533643, COSV56216778; called by muse, mutect2, varscan2
- VWA3A | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.06); catalogued as COSV67011752; called by muse, mutect2, varscan2
- VWA3B | c.3260C>T p.A1087V | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as rs756925311, COSV101289441, COSV69034121, COSV69034268; called by muse, mutect2, varscan2
- WASHC3 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as rs774556047, COSV53531425; called by muse, mutect2, varscan2
- WDR33 | c.3157C>T p.P1053S | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.043); catalogued as COSV59246734; called by muse, mutect2, varscan2
- WNK1 | c.2074G>A p.G692R | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.418); catalogued as COSV60027297; called by muse, mutect2, varscan2
- WWC2 | c.3376G>A p.E1126K | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.653); catalogued as COSV67856438; called by muse, mutect2, varscan2
- XIRP2 | c.8159A>C p.E2720A (on ENST00000628543; = p.E2895A on NM_152381.6) | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV54686555; called by muse, mutect2, varscan2
- ZEB2 | c.1621C>T p.Q541* | Nonsense Mutation (SNP) | VAF 21/71 reads (30%) | catalogued as COSV57952601; called by muse, mutect2, varscan2
- ZNF112 | c.2012G>A p.G671D (on ENST00000337401 / NM_001083335.2; = p.G665D on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (0.11); PolyPhen benign (0.217); catalogued as rs1275367562, COSV61619064; called by muse, mutect2, varscan2
- ZNF208 | c.1003C>T p.H335Y | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV68101777, COSV68102887; called by muse, mutect2, varscan2
- ZNF37A | c.1487G>A p.G496E | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100697283; called by muse, mutect2, varscan2
- ZNF607 | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs774059598, COSV67696379; called by muse, mutect2, varscan2
- ZNF646 | c.217G>A p.G73S | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV56212076; called by muse, mutect2, varscan2
- ZNF749 | c.2333C>T p.P778L | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs774118050, COSV61945304; called by muse, mutect2, varscan2
- ZNF793 | c.956C>T p.S319L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as rs192785678; called by muse, mutect2, varscan2
- ZP4 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV100850703, COSV63911226; called by muse, mutect2, varscan2
- ZRANB3 | c.1766C>T p.P589L | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1367199975, COSV51496418; called by muse, mutect2, varscan2
- ZSWIM4 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as COSV54319809; called by muse, mutect2, varscan2
- ZSWIM8 | c.2561C>T p.A854V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV67131376; called by muse, mutect2, varscan2
- BRWD1 | c.3105G>A p.M1035I | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- MMP2 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.79); PolyPhen benign (0.12); called by muse, mutect2
- MS4A2 | c.187-1_194del p.X63_splice | Splice Site (DEL) | VAF 21/103 reads (20%) | called by mutect2, pindel, varscan2
- ACAA2 | c.826C>T p.L276= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV53270110; called by muse, mutect2, varscan2
- ACKR1 | c.735C>T p.I245= | Silent (SNP) | VAF 34/116 reads (29%) | catalogued as rs769856005, COSV63671974; called by muse, mutect2, varscan2
- ACOX1 | c.1722C>T p.F574= | Silent (SNP) | VAF 40/119 reads (34%) | catalogued as COSV53132143; called by muse, mutect2, varscan2
- ACTG1 | c.501G>A p.E167= | Silent (SNP) | VAF 42/106 reads (40%) | catalogued as COSV100111860; called by muse, mutect2, varscan2
- ADAMTS7 | c.192C>T p.P64= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs545729024, COSV66306192; called by muse, mutect2, varscan2
- ADAP2 | c.1059G>A p.L353= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV58295257; called by muse, mutect2, varscan2
- ADAR | c.462G>A p.K154= | Silent (SNP) | VAF 47/106 reads (44%) | catalogued as COSV52712845; called by muse, mutect2, varscan2
- ADCY8 | c.2391C>T p.F797= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs267601771, COSV53897529, COSV99654296; called by muse, mutect2, varscan2
- ADCY8 | c.1134C>T p.L378= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as rs1040498305, COSV53898816; called by mutect2, varscan2
- ADGRB3 | c.2409G>A p.L803= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV100999995; called by muse, mutect2, varscan2
- ADGRL2 | c.576C>T p.F192= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs773672775, COSV54656037; called by muse, mutect2, varscan2
- ANKRD30A | c.402C>T p.L134= (on ENST00000611781; = p.L78= on NM_052997.2) | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs914914903, COSV64609437, COSV64614180; called by muse, mutect2, varscan2
- ARHGAP36 | c.672G>A p.R224= | Silent (SNP) | VAF 23/30 reads (77%) | catalogued as COSV52264659; called by muse, mutect2, varscan2
- ATF6 | c.48C>T p.S16= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as COSV63406290; called by muse, mutect2, varscan2
- BACE1 | c.312C>T p.A104= | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as COSV57284009; called by muse, mutect2, varscan2
- BCAP31 | c.231G>A p.T77= | Silent (SNP) | VAF 60/82 reads (73%) | catalogued as COSV61451314; called by muse, mutect2, varscan2
- BIRC6 | c.10413G>A p.R3471= | Silent (SNP) | VAF 37/103 reads (36%) | catalogued as COSV70196419; called by muse, mutect2, varscan2
- BRPF1 | c.2368C>T p.L790= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as rs746015047, COSV57403550; called by muse, mutect2, varscan2
- C12orf40 | c.12C>T p.V4= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV61129954, COSV61133699; called by muse, mutect2, varscan2
- C1QTNF9 | c.393T>C p.G131= | Silent (SNP) | VAF 9/14 reads (64%) | called by muse, mutect2, varscan2
- C1RL | c.1053G>T p.L351= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV56923784; called by muse, mutect2, varscan2
- C4orf50 | c.732C>T p.L244= (on ENST00000324058; = p.L1476= on NM_001364689.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as COSV60687785; called by muse, mutect2, varscan2
- C7 | c.2388G>A p.E796= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV57471841; called by muse, mutect2, varscan2
- C8orf74 | c.810C>T p.T270= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs781682797, COSV58753637; called by muse, mutect2, varscan2
- CA9 | c.504C>T p.P168= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV65675098; called by muse, mutect2, varscan2
- CACNA1B | c.2058C>T p.S686= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV53116752; called by muse, mutect2, varscan2
- CACNA1C | c.3654C>T p.S1218= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as rs776884902, COSV59701494; ClinVar: likely benign; called by muse, mutect2, varscan2
- CACNA2D4 | c.1959C>T p.S653= | Silent (SNP) | VAF 25/46 reads (54%) | catalogued as COSV54946217; called by muse, mutect2, varscan2
- CACNA2D4 | c.1818C>T p.A606= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV54946236; called by muse, mutect2, varscan2
- CALN1 | c.573G>A p.K191= (on ENST00000329008 / NM_001017440.3; = p.K233= on NM_031468.4) | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as COSV61122339; called by muse, mutect2, varscan2
- CAMTA1 | c.1779G>A p.K593= | Silent (SNP) | VAF 29/78 reads (37%) | catalogued as rs1226299016, COSV57885481; called by muse, mutect2, varscan2
- CDH11 | c.1863C>T p.I621= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs866544694, COSV51753477; called by muse, mutect2, varscan2
- CDS1 | c.1026G>A p.L342= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as COSV55686912; called by muse, mutect2, varscan2
- CFAP100 | c.615G>A p.R205= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV61502541; called by muse, mutect2, varscan2
- CFAP20DC | c.429C>T p.T143= (on ENST00000482387 / NM_001351530.2; = p.T18= on NM_198463.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as COSV55917110; called by muse, mutect2, varscan2
- CHAF1B | c.1152G>A p.L384= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as COSV58439415; called by muse, mutect2, varscan2
- CHD1 | c.3912C>T p.T1304= | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as rs1159501001, COSV52337994; called by muse, mutect2, varscan2
- CLCN1 | c.273G>A p.K91= | Silent (SNP) | VAF 44/181 reads (24%) | catalogued as COSV58367971; called by muse, mutect2, varscan2
- CLU | c.432G>A p.L144= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV57065902; called by muse, varscan2
- CNBD1 | c.1182G>A p.G394= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV73072623; called by muse, mutect2, varscan2
- CNTLN | c.2763G>A p.Q921= | Silent (SNP) | VAF 55/171 reads (32%) | catalogued as COSV52068904; called by muse, mutect2, varscan2
- COL13A1 | c.2016G>A p.K672= (on ENST00000398978 / NM_001130103.2; = p.K600= on NM_080798.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV62567664; called by muse, mutect2, varscan2
- COL22A1 | c.9C>T p.G3= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as COSV100276638, COSV100279544; called by muse, varscan2
- CRLF1 | c.495C>T p.L165= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as COSV66504226, COSV66504261; called by muse, varscan2
- CRTAC1 | c.327C>T p.D109= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV54011921; called by muse, varscan2
- CTNND2 | c.1185C>A p.S395= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV58870579; called by muse, mutect2, varscan2
- CYP4F3 | c.1407C>T p.I469= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV55407649; called by muse, mutect2, varscan2
- DHCR7 | c.1119G>A p.R373= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as rs1271613914, COSV62794647; called by muse, mutect2, varscan2
- DHRS7C | c.75G>A p.E25= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV100364812, COSV57649869; called by muse, mutect2, varscan2
- DIP2C | c.42G>A p.E14= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV55148955; called by muse, mutect2
- DMP1 | c.1167G>A p.S389= | Silent (SNP) | VAF 66/164 reads (40%) | catalogued as rs756632847, COSV56818871; called by muse, mutect2, varscan2
- DNA2 | c.1719C>T p.T573= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs1295862594, COSV64427671; called by muse, mutect2
- DPYD | c.609T>A p.A203= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV64592432; called by muse, mutect2, varscan2
- DTX1 | c.1680C>T p.I560= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV55654299; called by muse, mutect2, varscan2
- DUSP7 | c.861C>T p.H287= | Silent (SNP) | VAF 58/149 reads (39%) | catalogued as rs751414622, COSV56588725; called by muse, mutect2, varscan2
- EFCAB14 | c.789G>A p.L263= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV64238248; called by muse, mutect2, varscan2
- EFEMP1 | c.18C>T p.F6= | Silent (SNP) | VAF 45/111 reads (41%) | catalogued as rs182486751; called by muse, mutect2, varscan2
- EHMT2 | c.3291C>T p.Y1097= | Silent (SNP) | VAF 183/536 reads (34%) | catalogued as COSV57666254; called by muse, mutect2, varscan2
- ENPEP | c.576C>T p.F192= | Silent (SNP) | VAF 39/90 reads (43%) | catalogued as rs1245393852, COSV54447400; called by muse, mutect2, varscan2
- ENTPD7 | c.1194C>T p.A398= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV65112025; called by muse, mutect2, varscan2
- EPAS1 | c.2568C>T p.L856= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV55384746; called by muse, mutect2, varscan2
- EPB41L5 | c.93A>T p.T31= | Silent (SNP) | VAF 114/184 reads (62%) | catalogued as COSV55349658; called by muse, mutect2, varscan2
- EPPK1 | c.3312G>A p.R1104= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs1037342756, COSV73260911; called by muse, mutect2, varscan2
- EVC | c.2055C>T p.S685= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs1411366434, COSV53829904; called by muse, mutect2
- EXOC6B | c.814C>T p.L272= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV55547109; called by muse, mutect2, varscan2
- FAM170A | c.567G>A p.G189= | Silent (SNP) | VAF 39/101 reads (39%) | catalogued as COSV58924250; called by muse, mutect2, varscan2
- FAM171A1 | c.1236C>T p.T412= | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as COSV100968088; called by muse, mutect2, varscan2
- FAM91A1 | c.450G>A p.R150= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV58236046; called by muse, mutect2, varscan2
- FCER1A | c.600G>A p.E200= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV63666686; called by muse, mutect2, varscan2
- FRRS1 | c.843T>C p.P281= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs76965331, COSV54920836; called by muse, mutect2, varscan2
- FSTL4 | c.2226C>T p.S742= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as COSV54765511; called by muse, mutect2, varscan2
- GIGYF2 | c.2142G>A p.L714= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV65247220; called by muse, mutect2, varscan2
- GJD4 | c.78C>T p.F26= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV58702022; called by muse, mutect2, varscan2
- GMPPA | c.765C>T p.L255= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV58006221; called by muse, mutect2
- GPATCH3 | c.525G>A p.L175= | Silent (SNP) | VAF 25/51 reads (49%) | catalogued as COSV64651686; called by muse, mutect2, varscan2
- GPC3 | c.1732C>T p.L578= | Silent (SNP) | VAF 33/43 reads (77%) | catalogued as COSV63660123; called by muse, mutect2, varscan2
- GPR158 | c.2400G>A p.G800= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as rs1341254449, COSV66266498; called by muse, mutect2, varscan2
- GPSM1 | c.1596C>T p.T532= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as rs782338188, COSV52517124; called by muse, mutect2, varscan2
- GRAMD2B | c.147C>T p.S49= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as rs574081219, COSV99586971; called by muse, mutect2, varscan2
- HDAC4 | c.1944C>T p.T648= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV61860900; called by muse, mutect2, varscan2
- HECW1 | c.2727C>T p.A909= | Silent (SNP) | VAF 56/95 reads (59%) | catalogued as COSV101222901; called by muse, mutect2, varscan2
- HERC1 | c.11355T>A p.V3785= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV71246416; called by muse, mutect2, varscan2
- HS3ST4 | c.942G>T p.L314= | Silent (SNP) | VAF 61/173 reads (35%) | catalogued as COSV58804949; called by muse, mutect2, varscan2
- IFIT3 | c.699C>T p.A233= | Silent (SNP) | VAF 33/73 reads (45%) | catalogued as COSV51078107, COSV51079257; called by muse, mutect2, varscan2
- IGKV1D-42 | c.129C>T p.I43= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as rs1472279116; called by muse, mutect2, varscan2
- IGSF1 | c.2985C>T p.V995= | Silent (SNP) | VAF 45/60 reads (75%) | catalogued as COSV63836476; called by muse, mutect2, varscan2
- IMPG2 | c.1755C>T p.F585= | Silent (SNP) | VAF 36/92 reads (39%) | catalogued as COSV51974606; called by muse, mutect2, varscan2
- INPP5E | c.1401C>T p.T467= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV65495981; called by muse, mutect2, varscan2
- IQSEC1 | c.2373C>T p.F791= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as COSV56221792; called by muse, mutect2, varscan2
- KCNA1 | c.672G>A p.V224= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV66836720; called by muse, mutect2, varscan2
- KCNJ10 | c.804C>T p.L268= | Silent (SNP) | VAF 32/89 reads (36%) | catalogued as COSV63632999; called by muse, mutect2, varscan2
- KCNJ5 | c.399C>T p.L133= | Silent (SNP) | VAF 46/104 reads (44%) | catalogued as COSV57963834, COSV57967078; called by muse, mutect2, varscan2
- KIF1B | c.3009G>A p.R1003= (on ENST00000377086 / NM_001365952.1; = p.R957= on NM_015074.3) | Silent (SNP) | VAF 39/89 reads (44%) | catalogued as rs1162738316, COSV55804551; called by muse, mutect2, varscan2
- KY | c.1425C>T p.T475= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV71016657; called by muse, mutect2
- LCA5L | c.729G>A p.Q243= | Silent (SNP) | VAF 34/112 reads (30%) | catalogued as COSV55744141; called by muse, mutect2, varscan2
- LPA | c.153T>C p.A51= | Silent (SNP) | VAF 53/144 reads (37%) | catalogued as COSV60298168; called by muse, mutect2, varscan2
- LRRC15 | c.1140C>T p.L380= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV100752860, COSV61649632; called by muse, mutect2, varscan2
- MAGEA6 | c.702G>A p.R234= | Silent (SNP) | VAF 81/111 reads (73%) | catalogued as rs782762494, COSV100262695, COSV61449629; called by muse, mutect2, varscan2
- MAP3K9 | c.1884C>T p.T628= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs751840147, COSV67120246; called by muse, mutect2, varscan2
- MDN1 | c.9396C>T p.S3132= | Silent (SNP) | VAF 41/142 reads (29%) | catalogued as rs1294826063, COSV101020834; called by muse, mutect2, varscan2
- ME3 | c.1230C>T p.A410= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as COSV62771189; called by muse, mutect2, varscan2
- MEGF10 | c.1236C>T p.I412= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV57245788; called by muse, mutect2, varscan2
- MERTK | c.2538C>T p.T846= | Silent (SNP) | VAF 35/58 reads (60%) | catalogued as COSV54925455; called by muse, mutect2, varscan2
- MIPOL1 | c.1323G>A p.V441= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV59380439; called by muse, mutect2, varscan2
- MTMR4 | c.1905C>T p.N635= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as COSV60199568; called by muse, mutect2, varscan2
- MUC3A | c.6972C>T p.F2324= | Silent (SNP) | VAF 28/95 reads (29%) | called by muse, mutect2, varscan2
- MYH3 | c.3720G>A p.S1240= | Silent (SNP) | VAF 37/100 reads (37%) | catalogued as rs377201866; called by muse, mutect2, varscan2
- MYOCD | c.822G>A p.K274= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV58498627; called by muse, mutect2, varscan2
- NME3 | c.183C>T p.S61= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as rs774180238, COSV99167713; called by muse, varscan2
- OR10A6 | c.609C>T p.T203= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs372430463, COSV59164638; called by muse, mutect2, varscan2
- OR10S1 | c.42G>A p.T14= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as rs748517163, COSV73342691; called by muse, mutect2, varscan2
- OR2A25 | c.801G>A p.K267= | Silent (SNP) | VAF 180/338 reads (53%) | catalogued as COSV68716932, COSV68716938; called by muse, mutect2, varscan2
- OR2B6 | c.879G>A p.R293= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV55128563; called by muse, mutect2, varscan2
- OR2T6 | c.570G>A p.G190= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV100861489; called by muse, mutect2, varscan2
- OR52B4 | c.180C>T p.P60= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs554653438, COSV68768646; called by muse, mutect2, varscan2
- OR52E6 | c.93C>T p.F31= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV100259051, COSV61431511, COSV61432032; called by muse, mutect2
- OR6B2 | c.885G>A p.K295= | Silent (SNP) | VAF 50/137 reads (36%) | catalogued as COSV53152973; called by muse, mutect2, varscan2
- OR6C6 | c.126C>T p.I42= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV64455540; called by muse, mutect2, varscan2
- PAOX | c.973C>T p.L325= | Silent (SNP) | VAF 40/107 reads (37%) | catalogued as COSV53371434; called by muse, mutect2, varscan2
- PCDHAC2 | c.627G>A p.L209= | Silent (SNP) | VAF 19/31 reads (61%) | catalogued as rs1437861925, COSV53839590; called by muse, mutect2, varscan2
- PCDHGB4 | c.369C>T p.I123= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV53903175; called by muse, mutect2, varscan2
- PCK1 | c.516C>T p.I172= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as rs774522183, COSV60126589; called by muse, mutect2, varscan2
- PCSK5 | c.279C>T p.F93= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV65082729; called by muse, mutect2, varscan2
- PDZD4 | c.1125C>T p.L375= | Silent (SNP) | VAF 28/35 reads (80%) | catalogued as rs1557076143, COSV51245528; called by muse, mutect2, varscan2
- PIK3C2B | c.2319C>T p.F773= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV65809650; called by muse, mutect2, varscan2
- PIK3C2B | c.585C>T p.V195= | Silent (SNP) | VAF 133/304 reads (44%) | catalogued as rs772428461, COSV65803433; called by muse, mutect2, varscan2
- PKP2 | c.2589G>A p.K863= | Silent (SNP) | VAF 30/61 reads (49%) | catalogued as rs777477467, COSV50726605; ClinVar: likely benign; called by muse, mutect2, varscan2
- POLR3A | c.864C>T p.F288= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as rs764364652, COSV64930449; called by muse, mutect2, varscan2
- PPP6R3 | c.894T>C p.A298= | Silent (SNP) | VAF 63/134 reads (47%) | catalogued as COSV55722467; called by muse, mutect2, varscan2
- PRAMEF17 | c.336C>T p.F112= | Silent (SNP) | VAF 139/356 reads (39%) | catalogued as COSV65816157; called by muse, mutect2, varscan2
- PRUNE2 | c.6477A>G p.E2159= | Silent (SNP) | VAF 46/123 reads (37%) | catalogued as COSV65038587; called by muse, mutect2, varscan2
- PTPRF | c.3348C>T p.F1116= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as rs199683329, COSV63443266; called by muse, mutect2, varscan2
- PTPRR | c.990C>T p.P330= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV51726428; called by muse, mutect2, varscan2
- PTPRT | c.1212C>T p.T404= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV61965363; called by muse, mutect2, varscan2
- RAPGEF6 | c.2841C>T p.F947= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV57241474; called by muse, mutect2, varscan2
- RBMXL2 | c.687G>A p.R229= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV60978819; called by muse, mutect2, varscan2
- RBP3 | c.1704C>T p.I568= | Silent (SNP) | VAF 35/75 reads (47%) | called by muse, mutect2, varscan2
- RNF175 | c.900C>T p.I300= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV52605317; called by muse, mutect2
- RPS6KA1 | c.1485G>A p.G495= | Silent (SNP) | VAF 60/149 reads (40%) | catalogued as COSV65175443; called by muse, mutect2, varscan2
- SAMM50 | c.810C>T p.S270= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV100601404, COSV63109404; called by muse, mutect2, varscan2
- SELE | c.1164C>T p.F388= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as COSV60974276; called by muse, varscan2
- SERPINA9 | c.933C>T p.S311= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV54073199; called by muse, mutect2, varscan2
- SESN2 | c.717C>T p.S239= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs781477569, COSV53426876; called by muse, mutect2, varscan2
- SHE | c.837C>T p.S279= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as COSV59071029; called by muse, mutect2, varscan2
- SLC44A2 | c.1869C>T p.H623= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as COSV59835466; called by muse, mutect2, varscan2
- SLCO3A1 | c.327C>T p.I109= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as rs772866234, COSV59226005; called by muse, mutect2
- SORBS2 | c.1137C>T p.I379= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as COSV52993309; called by muse, mutect2, varscan2
- STRC | c.4647G>A p.V1549= | Silent (SNP) | VAF 38/60 reads (63%) | catalogued as rs1461589747, COSV100294454; called by muse, mutect2, varscan2
- STYXL2 | c.2928C>T p.S976= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as rs769257794, COSV54802776; called by muse, mutect2, varscan2
- SZT2 | c.9678G>A p.G3226= (on ENST00000634258 / NM_001365999.1; = p.G3169= on NM_015284.4) | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs1219829318, COSV65094230; called by mutect2, varscan2
- TAP1 | c.1446G>A p.L482= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV62753942; called by muse, mutect2, varscan2
- TAS2R7 | c.687C>T p.A229= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs1200968733, COSV53688099; called by muse, mutect2, varscan2
- TGM4 | c.93G>A p.T31= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs747399684, COSV56093047; called by muse, mutect2, varscan2
- TIAM2 | c.1176G>A p.R392= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as rs767466318, COSV100018130; called by muse, mutect2, varscan2
- TMEM106C | c.645G>A p.V215= | Silent (SNP) | VAF 95/259 reads (37%) | catalogued as COSV56742266; called by muse, mutect2, varscan2
- TMEM132B | c.1194G>A p.P398= | Silent (SNP) | VAF 43/106 reads (41%) | catalogued as rs754158975, COSV54746894, COSV54768582; called by muse, mutect2, varscan2
- TREML2 | c.681C>T p.S227= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV72439040; called by muse, mutect2, varscan2
- TRHDE | c.1461G>A p.R487= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV99669371; called by muse, mutect2, varscan2
- TRIM71 | c.1860C>T p.I620= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs1312075098, COSV67470295; called by muse, mutect2, varscan2
- TRRAP | c.4260C>T p.V1420= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as rs782180003, COSV62840498; called by muse, mutect2, varscan2
- TUBB6 | c.324G>A p.E108= | Silent (SNP) | VAF 46/88 reads (52%) | catalogued as COSV52313069; called by muse, mutect2, varscan2
- UBQLN3 | c.960G>A p.Q320= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as COSV61163455; called by muse, mutect2, varscan2
- VAT1L | c.246C>T p.F82= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV56815664; called by muse, mutect2, varscan2
- VPS51 | c.1020C>T p.F340= | Silent (SNP) | VAF 24/47 reads (51%) | catalogued as rs767698867, COSV54206309; called by muse, mutect2, varscan2
- XIRP2 | c.1740A>G p.K580= (on ENST00000628543; = p.K755= on NM_152381.6) | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as COSV54686542; called by muse, mutect2, varscan2
- ZFPM2 | c.780G>A p.R260= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as COSV65872777, COSV65874675; called by muse, mutect2, varscan2
- ZNF195 | c.1815C>T p.P605= (on ENST00000399602 / NM_001130520.3; = p.P533= on NM_007152.5) | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as COSV50002221; called by muse, mutect2, varscan2
- ZNF217 | c.2904C>T p.P968= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as rs768480969, COSV56594653; called by muse, mutect2, varscan2
- ZNF540 | c.1845C>T p.A615= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV57108285; called by muse, mutect2, varscan2
- ZNF618 | c.2791C>T p.L931= (on ENST00000374126 / NM_001318042.2; = p.L838= on NM_133374.2) | Silent (SNP) | VAF 45/139 reads (32%) | catalogued as COSV55917371; called by muse, mutect2, varscan2
- ZNF662 | c.477C>T p.V159= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV60241158; called by muse, mutect2, varscan2
- ZNF746 | c.1059G>A p.R353= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV61406579; called by muse, mutect2, varscan2
- ZNF831 | c.1704G>A p.E568= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV64038078; called by muse, mutect2, varscan2
- ABR | c.247-8295G>A | Intron (SNP) | VAF 12/31 reads (39%) | catalogued as COSV99347548; called by muse, mutect2, varscan2
- COMMD9 | chr11:36271742 G>A | 3'Flank (SNP) | VAF 15/65 reads (23%) | called by muse, mutect2, varscan2
- COMMD9 | chr11:36271743 G>A | 3'Flank (SNP) | VAF 15/63 reads (24%) | called by muse, mutect2, varscan2
- DCHS2 | n.4152G>A | RNA (SNP) | VAF 10/28 reads (36%) | catalogued as COSV100601056, COSV61768903; called by muse, mutect2, varscan2
- FAM86C1P | n.508G>A | RNA (SNP) | VAF 39/120 reads (33%) | catalogued as rs1176543676, COSV60638129; called by muse, mutect2, varscan2
- FBXL21P | n.1590G>A | RNA (SNP) | VAF 15/38 reads (39%) | catalogued as COSV51808374; called by muse, mutect2, varscan2
- HNF4A | c.1129+94C>T | Intron (SNP) | VAF 78/211 reads (37%) | catalogued as rs751922253, COSV100291130; called by muse, mutect2, varscan2
- MIR520D | n.40G>T | RNA (SNP) | VAF 42/129 reads (33%) | called by muse, mutect2, varscan2
- MIRLET7C | n.76C>T | RNA (SNP) | VAF 16/35 reads (46%) | called by muse, mutect2, varscan2
- OBSCN | c.4585+2741T>A | Intron (SNP) | VAF 30/78 reads (38%) | catalogued as COSV99473803; called by muse, mutect2, varscan2
- OBSCN | c.18662-2101G>A | Intron (SNP) | VAF 6/30 reads (20%) | catalogued as COSV99473807; called by muse, mutect2
- SBF1 | c.*299C>G | 3'UTR (SNP) | VAF 5/13 reads (38%) | catalogued as COSV99323908; called by muse, mutect2, varscan2
- SNORD115-1 | n.67G>A | RNA (SNP) | VAF 95/293 reads (32%) | called by muse, mutect2, varscan2
